TCGA case TCGA-ET-A3DO — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Johns Hopkins. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0cafefef-911b-46e8-9e6c-19a0e7d555aa

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 33 years; Vital status: Alive.

Diagnoses (3)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 33.3 years (12,158 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 3,552 days (9.7 years); Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Measurement unit: Centimeters; Tumor depth measurement: 1.5; Tumor length measurement: 2.5; Tumor width measurement: 1.8.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 58 days; Days to treatment end: 58 days; Treatment dose: 80 mCi; Treatment outcome: Complete Response; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 80; Prescribed dose units: mCi; Pretreatment: Thyroxine Withdrawal; Timepoint category: First Treatment.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 80 mCi; Pretreatment: Thyroxine Withdrawal.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation, External Beam.
2. Recurrence of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Lymph node, NOS. Age at diagnosis: 34.8 years (12,728 days); Days to diagnosis: 570 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 660 days (1.8 years).
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.
3. Recurrence of diagnosis 1 (Papillary adenocarcinoma, NOS), site: Lymph node, NOS. Age at diagnosis: 35.1 years (12,817 days); Days to diagnosis: 659 days (1.8 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease; Days to treatment start: 659 days (1.8 years).

Follow-up (8 entries)
- Day 570 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 570 days (1.6 years); Evidence of recurrence type: Histologic Confirmation.
- Day 659 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 659 days (1.8 years); Evidence of recurrence type: Histologic Confirmation; Histologic progression: No.
- Days to follow up: 2,095 days (5.7 years); Disease response: Tumor Free.
- Days to follow up: 2,458 days (6.7 years); Disease response: Tumor Free.
- Days to follow up: 2,948 days (8.1 years); Disease response: Tumor Free.
- Days to follow up: 3,552 days (9.7 years); Disease response: Tumor Free.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.
- Follow-up contact recording only the day: within 3 months of surgery.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-ET-A3DO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-ET-A3DO-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-ET-A3DO-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-ET-A3DO-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Classical/usual; Laterality: Right lobe; Lymph nodes preop imaging: No; Lymph nodes examined: No; Genotypic analysis detected: No.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy.
- Follow-up form 2: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment dose: 80 mCi; I 131 radiation treatment cumulative dose: 80 mCi; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 3,552 days; disease-specific survival: no event (censored), 3,552 days; disease-free interval: event (new tumor event after initially disease-free), 570 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 570 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-ET-A3DO-01A-11D-A19I-01): tumor purity 0.6, ploidy 2, whole-genome doublings 0.
